Somatic mutation profile of tumor specimen TCGA-DX-A3LW-01A (aliquot TCGA-DX-A3LW-01A-21D-A21Q-09) from TCGA case TCGA-DX-A3LW, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 43.7 years (15,969 days).
Specimen TCGA-DX-A3LW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a65f4c59-a30c-4287-a1fd-cf12fd93e2a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A3LW-10A (Blood Derived Normal), aliquot TCGA-DX-A3LW-10A-01D-A21Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd8b38d7-9182-41b1-a59b-081dea65e97a

The open-access MAF lists 30 somatic variants for this specimen: 19 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 10, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANO7 | c.898A>T p.T300S (on ENST00000274979; = p.T246S on NM_001370694.2) | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV99239501; called by muse, mutect2
- EPHB2 | c.802G>A p.V268I | Missense Mutation (SNP) | VAF 35/46 reads (76%) | SIFT tolerated (0.42); PolyPhen benign (0.06); catalogued as rs369702152; called by muse, mutect2, varscan2
- GREB1 | c.5773C>T p.R1925W | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755838573, COSV52179636; called by muse, mutect2, varscan2
- NRP2 | c.1411C>T p.R471C | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746710925; called by muse, mutect2, varscan2
- OPRM1 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs552231464, COSV100000392; called by muse, mutect2, varscan2
- PEX11B | c.755A>G p.Y252C | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1317727898; called by muse, mutect2, varscan2
- TRIM40 | c.580G>A p.D194N (on ENST00000376724; = p.D165N on NM_138700.4) | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV100325473; called by muse, mutect2
- WIF1 | c.922C>T p.P308S | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs748455979, COSV54133665, COSV54134913; called by muse, mutect2, varscan2
- CHRNA9 | c.246G>T p.W82C | Missense Mutation (SNP) | VAF 36/274 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CNPY2 | c.168C>G p.F56L | Missense Mutation (SNP) | VAF 81/627 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- DIP2B | c.3641G>A p.S1214N | Missense Mutation (SNP) | VAF 99/182 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EEF1AKMT3 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 101/640 reads (16%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- FLG | c.11729C>A p.A3910D | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- HNRNPUL1 | c.1688-20_1702del p.X563_splice | Splice Site (DEL) | VAF 12/87 reads (14%) | called by mutect2, pindel, varscan2
- KIF26A | c.1410C>A p.H470Q | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- SEC14L3 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SEL1L3 | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 12/379 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.253); called by muse, mutect2
- TNR | c.1877T>G p.V626G | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WRN | c.854T>G p.L285R | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CDKAL1 | c.528G>C p.V176= | Silent (SNP) | VAF 23/33 reads (70%) | called by muse, mutect2, varscan2
- CTNND2 | c.3192G>A p.V1064= | Silent (SNP) | VAF 9/71 reads (13%) | called by muse, mutect2
- DDAH1 | c.771G>C p.L257= | Silent (SNP) | VAF 10/55 reads (18%) | called by muse, mutect2, varscan2
- GPR37 | c.489G>T p.G163= | Silent (SNP) | VAF 22/51 reads (43%) | called by muse, mutect2, varscan2
- HSD3B1 | c.591C>T p.F197= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as rs1557896917; called by muse, mutect2, varscan2
- MARCHF4 | c.210C>T p.P70= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as rs1324079963; called by muse, mutect2, varscan2
- OS9 | c.1386G>A p.R462= | Silent (SNP) | VAF 80/163 reads (49%) | called by muse, mutect2, varscan2
- PKD1L2 | c.1524C>T p.R508= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as rs761253108, COSV61420331; called by muse, mutect2, varscan2
- SATB2 | c.262C>A p.R88= | Silent (SNP) | VAF 3/46 reads (7%) | catalogued as COSV53484706, COSV99612569, COSV99612749; called by muse, mutect2
- SIN3A | c.45C>T p.A15= | Silent (SNP) | VAF 17/32 reads (53%) | called by muse, mutect2, varscan2
- IL36B | c.261+1008C>A | Intron (SNP) | VAF 18/97 reads (19%) | called by muse, mutect2, varscan2
